Surgical pathology report (de-identified scan), TCGA case TCGA-FG-8187, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-8187-01A (Primary Tumor).

[page 1 of 10]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED]

SPECIMEN SUBMITTED:

Part A: RIGHT FRONTAL TUMOR

Part B: RIGHT FRONTAL MASS #2

Final Diagnosis

Right frontal lobe, excisional biopsy (A, B) - Low-grade oligoastrocytoma (WHO grade II).
- See comment.

REPORT

Diagnosis Comment:

The neoplasm has roughly equal amounts of geographically distinct areas of classic oligodendroglioma and astrocytoma. There is one focus in the oligodendroglioma area with increased cellularity and pleomorphism. Mitotic figures are extremely rare. Ki-67 labeling index is 8.4% in the hypercellular area and 9.6% in another area. There is no evidence of vascular proliferation or necrosis.

Brain and Spinal Cord Tumor Case Summary:

Specimen type: Resection

Specimen handling: Frozen section and permanent section

Site: Frontal lobe

Laterality: Right

Diagnosis: Low-grade oligoastrocytoma

WHO Grade: II

Ancillary test(s) ordered: Immunohistochemistry for Ki-67 and p53, FISH for 1p, 19q, and EGFR, all performed on block A3. FISH will be reported in an addendum.

REPORT

classic oligodendro-
cytoma and astrocytoma
with increased cellularity and
pleomorphism in the
oligodendroglioma area and 9.6%

[page 2 of 10]
SURGICAL PATHOLOGY REPORT

Procedure: ADDENDUM

Status: Signed Out

Text: No nuclei label with antibodies to p53.

[page 3 of 10]
SURGICAL PATHOLOGY REPORT

Procedure: FISH for 1p/19q

Status: Signed Out

Text: ***** 1p/19q FISH RESULTS *****

RESULTS

Chromosome 1p: Loss, eusomic
Chromosome 19q: Loss, eusomic

Quantitative FISH results:

1p36: 1.8
1q25: 2.7
1p36/1q25 ratio: 0.7

19q13: 1.7
19p13: 2.8
19q13/19p13 ratio: 0.6

SPECIMEN SUBMITTED: Paraffin block A3

INTERPRETATION

1p loss: A majority of nuclei showed a relative reduction in 1p36 signals, consistent with allelic loss of the short arm of chromosome 1 (1p).

19q loss: A majority of nuclei showed a relative reduction in 19q13 signals, consistent with allelic loss of the long arm of chromosome 19 (19q).

Allelic loss at one locus does not necessarily predict the presence of alterations at other loci on the same chromosome, i.e. FISH may not detect partial allelic loss. FISH may not detect allelic losses if there is loss of one allele and replication on the other allele.

Comment: Allelic loss on chromosome 1p has been shown to correlate with chemoresponsiveness and long progression-free survival in some gliomas. This correlation is stronger when there is concomitant allelic loss on 19q. An association of chemoresponsiveness and/or long progression-free survival with allelic loss on 19q in the absence of loss on 1p has not been established. In patients with 1p/19q loss, aneusomy for chromosome 1 and 19 may be associated with earlier recurrence.

Method: The integrity of the short arm of chromosome 1 (1p) and long arm of chromosome 19 (19q) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using locus-specific probes target (1p36, 19q13) and reference probes (1q25, 19p13).

[page 4 of 10]
SURGICAL PATHOLOGY REPORT

The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

Procedure: FISH for EGFR

Status: Signed Out

Text: ***** EGFR FISH RESULTS *****

RESULTS: EGFR NOT AMPLIFIED

SPECIMEN SUBMITTED: Paraffin block A3

Interpretation : Amplification of the Epidermal Growth Factor Receptor gene (EGFR) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using EGFR (7p12) and chromosome 7 paracentromeric (7p11.1-p11.1) (CEP7) locus specific directly labeled probes

The following FISH results were obtained:

EGFR 3.1

CEP7 2.8

EGFR/CEP7 ratio 1.1 (Reference Range 0.8-1.9)

Aneusomy of chromosome 7 is not identified.

Comment: There is some indication in the literature that EGFR amplification may correlate with survival and prognosis in some patients with gliomas.

[page 5 of 10]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

A. Low grade glioma.

Clinical Diagnosis:

HX BRAIN MASS, AVM

Gross Description:

A. Received fresh for frozen diagnosis labeled "right frontal tumor" are multiple fragments of tan-pink brain tissue aggregating to 3.0 x 2.0 x 1.0 cm, and weighing 2.32 grams. No firm areas are identified. A representative section is submitted for frozen diagnosis and kept frozen. The remaining tissue is submitted in formalin in cassettes A2-A4.

B. Received fresh on Telfa gauze labeled "right frontal mass #2" is an irregular shaped segment of tan brain tissue measuring 3.0 x 1.5 x 1.5 cm, and weighing 6.31 grams. Approximately half of the specimen is slightly firm on palpation. The specimen is sectioned to reveal a tan homogenous cut surface. The specimen is totally submitted in formalin as follows: B1-B3 firm area, B4-B6 remainder of tissue.

Microscopic:

{Not Entered}

[page 6 of 10]
SURGICAL PATHOLOGY REPORT

De-Identified Specimen Code: [REDACTED]

Patient Age/Sex [REDACTED]

SPECIMEN SUBMITTED:

Part A: RIGHT FRONTAL TUMOR

Part B: RIGHT FRONTAL MASS #2

Final Diagnosis

Right frontal lobe, excisional biopsy (A, B) - Low-grade oligoastrocytoma (WHO grade II).
- See comment.

REPORT

Diagnosis Comment:

The neoplasm has roughly equal amounts of geographically distinct areas of classic oligodendroglioma and astrocytoma. There is one focus in the oligodendroglioma area with increased cellularity and pleomorphism. Mitotic figures are extremely rare. Ki-67 labeling index is 8.4% in the hypercellular area and 9.6% in another area. There is no evidence of vascular proliferation or necrosis.

Brain and Spinal Cord Tumor Case Summary:

Specimen type: Resection

Specimen handling: Frozen section and permanent section

Site: Frontal lobe

Laterality: Right

Diagnosis: Low-grade oligoastrocytoma

WHO Grade: II

Ancillary test(s) ordered: Immunohistochemistry for Ki-67 and p53, FISH for 1p, 19q, and EGFR, all performed on block A3. FISH will be reported in an addendum.

REPORT

classic oligodendroglioma
cellularity and pleomorphism
hypercellular area and 9.6%

[page 7 of 10]
SURGICAL PATHOLOGY REPORT

Procedure: ADDENDUM

Status: Signed Out

Text: No nuclei label with antibodies to p53.

[page 8 of 10]
SURGICAL PATHOLOGY REPORT

Procedure: FISH for 1p/19q

Status: Signed Out

Text: ***** 1p/19q FISH RESULTS *****

RESULTS

Chromosome 1p: Loss, eusomic
Chromosome 19q: Loss, eusomic

Quantitative FISH results:

1p36: 1.8

1q25: 2.7

1p36/1q25 ratio: 0.7

19q13: 1.7

19p13: 2.8

19q13/19p13 ratio: 0.6

SPECIMEN SUBMITTED: Paraffin block A3

INTERPRETATION

1p loss: A majority of nuclei showed a relative reduction in 1p36 signals, consistent with allelic loss of the short arm of chromosome 1 (1p).

19q loss: A majority of nuclei showed a relative reduction in 19q13 signals, consistent with allelic loss of the long arm of chromosome 19 (19q).

Allelic loss at one locus does not necessarily predict the presence of alterations at other loci on the same chromosome, i.e. FISH may not detect partial allelic loss. FISH may not detect allelic losses if there is loss of one allele and replication on the other allele.

Comment: Allelic loss on chromosome 1p has been shown to correlate with chemoresponsiveness and long progression-free survival in some gliomas. This correlation is stronger when there is concomitant allelic loss on 19q. An association of chemoresponsiveness and/or long progression-free survival with allelic loss on 19q in the absence of loss on 1p has not been established. In patients with 1p/19q loss, aneusomy for chromosome 1 and 19 may be associated with earlier recurrence.

Method: The integrity of the short arm of chromosome 1 (1p) and long arm of chromosome 19 (19q) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using locus-specific probes target (1p36, 19q13) and reference probes (1q25, 19p13)

[page 9 of 10]
SURGICAL PATHOLOGY REPORT

The analysis was performed on areas of glial neoplasm and only atypical nuclei with two or more reference probe signals were counted. Reported quantitative data represents an average of 40 nuclei. Loss is defined as a ratio of less than or equal to 0.7. Aneusomy is defined as a mean of greater than or equal to 3.0 for the reference probe signals (1q25, 19p13).

Procedure: FISH for EGFR

Status: Signed Out

Text: ***** EGFR FISH RESULTS *****

RESULTS: EGFR NOT AMPLIFIED

SPECIMEN SUBMITTED: Paraffin block A3

Interpretation : Amplification of the Epidermal Growth Factor Receptor gene (EGFR) was evaluated with interphase fluorescence in situ hybridization (FISH) on formalin-fixed paraffin embedded tissue sections using EGFR (7p12) and chromosome 7 paracentromeric (7p11.1-q11.1) (CEP7) locus specific directly labeled probes

The following FISH results were obtained:

EGFR 3.1

CEP7 2.8

EGFR/CEP7 ratio 1.1 (Reference Range 0.8 -1.9)

Aneusomy of chromosome 7 is not identified.

Comment: There is some indication in the literature that EGFR amplification may correlate with survival and prognosis in some patients with gliomas.

[page 10 of 10]
SURGICAL PATHOLOGY REPORT

Intraoperative Diagnosis:

A. Low grade glioma.

Clinical Diagnosis:

HX BRAIN MASS, [REDACTED]

Gross Description:

A. Received fresh for frozen diagnosis labeled "right frontal tumor" are multiple fragments of tan-pink brain tissue aggregating to 3.0 x 2.0 x 1.0 cm, and weighing 2.32 grams. No firm areas are identified. A representative section is submitted for frozen diagnosis and kept frozen. The remaining tissue is submitted in formalin in cassettes A2-A4.

B. Received fresh on Telfa gauze labeled "right frontal mass #2" is an irregular shaped segment of tan brain tissue measuring 3.0 x 1.5 x 1.5 cm, and weighing 6.31 grams. Approximately half of the specimen is slightly firm on palpation. The specimen is sectioned to reveal a tan homogenous cut surface. The specimen is totally submitted in formalin as follows: B1-B3 firm area, B4-B6 remainder of tissue.

Microscopic:

{Not Entered}

Source: NCI Genomic Data Commons file d7b941ed-0421-432c-bd42-3a13df592f51 (TCGA-FG-8187.7FEE5178-B1FF-4D7C-BEED-673236F8D485.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).